Somatic mutation profile of tumor specimen MBCproject_0253_T1_WES (aliquot MBCproject_0253_T1_WES_1) from CMI case MBCproject_0253, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCproject_0253_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21aea899-6b21-46d3-b83a-00d5367f89f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCproject_0253_SALIVA (Saliva), aliquot MBCproject_0253_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e93981e4-9ae2-46ea-bded-6f14ea704a81

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Intron 2, 3'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATG9B | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV52502619, COSV99873717; called by muse, mutect2
- ATRX | c.5494G>A p.E1832K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100971495, COSV64870656; called by muse, mutect2, varscan2
- CLSTN2 | c.2459G>A p.R820Q | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs560530846, COSV71722438; called by muse, mutect2, varscan2
- DENND2D | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62958866; called by muse, mutect2, varscan2
- FAM220A | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1220499982; called by muse, mutect2, varscan2
- FAM71A | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 126/446 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as rs774610252, COSV54236643; called by muse, varscan2
- LPAR2 | c.992G>C p.G331A | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV68351954; called by muse, mutect2, varscan2
- LRRC4B | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV65349239; called by muse, mutect2
- NOP53 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 66/273 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs751613426, COSV55882420; called by muse, mutect2, varscan2
- NRTN | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs748453602, COSV54607643; called by muse, mutect2, varscan2
- SCIMP | c.42G>A p.W14* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV68311508; called by muse, mutect2, varscan2
- TTLL8 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 76/316 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368466810; called by muse, mutect2, varscan2
- ZFAT | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64736359; called by muse, mutect2, varscan2
- ZP4 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 23/540 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.276); catalogued as COSV63912091; called by muse, mutect2
- BCORL1 | c.2483_2484dup p.L829Sfs*25 | Frame Shift Ins (INS) | VAF 29/264 reads (11%) | called by mutect2, pindel
- MKNK1 | c.1249G>C p.D417H | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AP3B2 | c.2388C>T p.S796= | Silent (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2
- GPR78 | c.240A>G p.Q80= | Silent (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- ZBTB21 | c.1314G>A p.S438= | Silent (SNP) | VAF 84/299 reads (28%) | catalogued as rs373668283, COSV100177128; called by muse, mutect2, varscan2
- ZNF720 | c.195G>A p.V65= | Silent (SNP) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- CEP170B | c.*1668T>G | 3'UTR (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- REV3L | c.9043-618T>A | Intron (SNP) | VAF 5/45 reads (11%) | catalogued as rs1356395055; called by muse, mutect2, varscan2
- SPDL1 | c.1670+112T>C | Intron (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
